Somatic mutation profile of tumor specimen TCGA-HC-A48F-01A (aliquot TCGA-HC-A48F-01A-11D-A257-08) from TCGA case TCGA-HC-A48F, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 47.7 years (17,434 days).
Specimen TCGA-HC-A48F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17fb5eeb-aff8-46c4-9d38-20a796c20a0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A48F-10A (Blood Derived Normal), aliquot TCGA-HC-A48F-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea0dfaf5-1d73-4f4e-a28c-905df157c5bb

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.421T>G p.C141G | Missense Mutation (SNP) | VAF 21/38 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519978, COSV52675559, COSV52751154, COSV52796306, COSV53037181; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC005833.1 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious, low confidence (0); catalogued as rs756775420, COSV52895128; called by muse, mutect2, varscan2
- ADGRL2 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.097); catalogued as COSV54657357; called by muse, mutect2, varscan2
- ASIC5 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV72232564; called by muse, mutect2, varscan2
- CTH | c.120dup p.I41Hfs*19 | Frame Shift Ins (INS) | VAF 21/60 reads (35%) | catalogued as rs1557458635; called by mutect2, pindel, varscan2
- GIMAP5 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 80/165 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs202237347; called by muse, mutect2, varscan2
- MAD2L2 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.091); catalogued as rs771992289, COSV52415654; called by muse, mutect2, varscan2
- MRPS25 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.192); catalogued as COSV53741122; called by muse, mutect2
- MTOR | c.4504A>G p.T1502A | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs748220176, COSV63869216; called by muse, mutect2, varscan2
- MYT1L | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.026); catalogued as rs774451946, COSV67707093; called by muse, mutect2, varscan2
- PI4KA | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.026); catalogued as COSV55406472; called by muse, mutect2, varscan2
- POLE | c.3659T>C p.L1220P | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57676059; called by muse, mutect2, varscan2
- SPATA31A1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.042); catalogued as rs1441645734; called by mutect2, varscan2
- TAF1L | c.3481G>A p.G1161R | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV54259359; called by muse, mutect2, varscan2
- TNIK | c.2848G>A p.V950I | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.195); catalogued as rs201681163, COSV52676546; called by muse, mutect2, varscan2
- ZBBX | c.2263G>T p.V755F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV56784884; called by muse, mutect2, varscan2
- ZBTB16 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1346143359, COSV60088891; called by muse, mutect2, varscan2
- PPFIA3 | c.2809-1G>A p.X937_splice | Splice Site (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- ALPK3 | c.4089T>G p.P1363= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as COSV51931058; called by muse, mutect2, varscan2
- APOL5 | c.939C>T p.S313= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV50766457; called by muse, mutect2, varscan2
- FTMT | c.534C>T p.H178= | Silent (SNP) | VAF 68/93 reads (73%) | catalogued as COSV100360479, COSV58419952; called by muse, mutect2, varscan2
- GTF2E2 | c.841C>T p.L281= | Silent (SNP) | VAF 35/42 reads (83%) | catalogued as COSV63478205; called by muse, mutect2, varscan2
- PDZD2 | c.6411A>G p.A2137= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs1265385803, COSV56853435; called by muse, mutect2, varscan2
- SHPRH | c.1974C>T p.R658= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as COSV51606062; called by muse, mutect2, varscan2
- SLA2 | c.258C>T p.H86= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs774530167, COSV53410495; called by muse, mutect2, varscan2
